Somatic mutation profile of tumor specimen TCGA-67-3773-01A (aliquot TCGA-67-3773-01A-01D-1040-01) from TCGA case TCGA-67-3773, project TCGA-LUAD (Lung Adenocarcinoma). Sex at birth: female; Vital status: Alive; Primary diagnosis: Adenocarcinoma, NOS; Tissue or organ of origin: Lower lobe, lung; AJCC pathologic stage: Stage IB; Age at diagnosis: 84.1 years (30,706 days).
Specimen TCGA-67-3773-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 1e76b510-baea-41cf-b6be-365060c7a45d.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-67-3773-10A (Blood Derived Normal), aliquot TCGA-67-3773-10A-01D-1489-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/b1211dbb-5d1a-48c2-8ff5-f92a0bbbd232

The open-access MAF lists 106 somatic variants for this specimen: 86 protein-altering or splice-affecting, 18 silent, 2 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 74, Silent 18, Nonsense Mutation 6, Frame Shift Del 4, Splice Site 2, 5'UTR 1, RNA 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- KRAS | c.35G>T p.G12V | Missense Mutation (SNP) | VAF 8/33 reads (24%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.972); catalogued as rs121913529, COSV55497369, COSV55497419, COSV55497479; ClinVar: likely pathogenic / pathogenic; called by muse, mutect2, varscan2
- ANKRD24 | c.1802C>A p.P601H | Missense Mutation (SNP) | VAF 19/44 reads (43%) | SIFT tolerated, low confidence (0.12); PolyPhen benign (0.201); catalogued as COSV53669481; called by muse, mutect2, varscan2
- ANKRD42 | c.194G>T p.G65V | Missense Mutation (SNP) | VAF 25/84 reads (30%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.951); catalogued as rs1273995312, COSV52615394; called by muse, mutect2, varscan2
- ASXL3 | c.4073T>C p.V1358A | Missense Mutation (SNP) | VAF 153/486 reads (31%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.251); catalogued as COSV52463214; called by muse, mutect2, varscan2
- ATP7B | c.2092A>G p.I698V | Missense Mutation (SNP) | VAF 27/108 reads (25%) | SIFT tolerated (0.35); PolyPhen benign (0); catalogued as COSV54437354; called by muse, mutect2, varscan2
- CACNA1C | c.6039C>A p.S2013R (on ENST00000399634 / NM_001167625.1; = p.S1942R on NM_000719.7) | Missense Mutation (SNP) | VAF 48/167 reads (29%) | SIFT tolerated, low confidence (0.62); PolyPhen probably damaging (0.962); catalogued as COSV59709729; called by muse, mutect2, varscan2
- CCDC116 | c.1528C>T p.Q510* | Nonsense Mutation (SNP) | VAF 99/256 reads (39%) | catalogued as rs1480273752, COSV53040120, COSV53040830; called by muse, mutect2, varscan2
- CDH20 | c.118C>A p.Q40K | Missense Mutation (SNP) | VAF 14/126 reads (11%) | SIFT tolerated (0.95); PolyPhen benign (0); catalogued as COSV53008046; called by muse, mutect2, varscan2
- COL12A1 | c.5857C>T p.R1953C | Missense Mutation (SNP) | VAF 14/77 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.97); catalogued as rs777948762, COSV59393496; called by muse, mutect2, varscan2
- CTNND1 | c.1133G>T p.R378L | Missense Mutation (SNP) | VAF 44/178 reads (25%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.694); catalogued as COSV62383024; called by muse, mutect2, varscan2
- CYP4F12 | c.241T>A p.S81T | Missense Mutation (SNP) | VAF 87/312 reads (28%) | SIFT tolerated (0.15); PolyPhen benign (0.048); catalogued as COSV61173321; called by muse, mutect2, varscan2
- CYP4F3 | c.508A>T p.S170C | Missense Mutation (SNP) | VAF 82/245 reads (33%) | SIFT tolerated (0.17); PolyPhen benign (0.107); catalogued as COSV55408917; called by muse, mutect2, varscan2
- DLGAP3 | c.1079C>T p.A360V | Missense Mutation (SNP) | VAF 78/242 reads (32%) | SIFT tolerated (0.39); PolyPhen benign (0.095); catalogued as COSV52393185; called by muse, mutect2, varscan2
- DNHD1 | c.12097G>A p.E4033K | Missense Mutation (SNP) | VAF 21/59 reads (36%) | SIFT tolerated (0.52); PolyPhen benign (0.093); catalogued as COSV54433612; called by muse, mutect2, varscan2
- EPHA6 | c.1486G>T p.V496L | Missense Mutation (SNP) | VAF 13/43 reads (30%) | SIFT tolerated (0.1); PolyPhen probably damaging (0.981); catalogued as COSV67568245; called by muse, mutect2, varscan2
- ERICH3 | c.3299C>A p.A1100E | Missense Mutation (SNP) | VAF 64/224 reads (29%) | SIFT tolerated (0.55); PolyPhen benign (0.001); catalogued as COSV58604279; called by muse, mutect2, varscan2
- ERICH5 | c.901C>T p.P301S | Missense Mutation (SNP) | VAF 50/144 reads (35%) | SIFT tolerated (0.07); PolyPhen benign (0.017); catalogued as rs758218194, COSV59315578; called by muse, mutect2, varscan2
- FAM234B | c.1598T>A p.L533H | Missense Mutation (SNP) | VAF 65/175 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV52194130; called by muse, mutect2, varscan2
- FCF1 | c.256T>G p.L86V | Missense Mutation (SNP) | VAF 114/185 reads (62%) | SIFT tolerated (0.21); PolyPhen benign (0.007); catalogued as COSV58696420; called by muse, mutect2, varscan2
- GEM | c.286G>T p.A96S | Missense Mutation (SNP) | VAF 74/232 reads (32%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.926); catalogued as COSV52597178; called by muse, mutect2, varscan2
- GLUD2 | c.835G>T p.G279W | Missense Mutation (SNP) | VAF 68/138 reads (49%) | SIFT deleterious (0); PolyPhen probably damaging (0.971); catalogued as COSV100047190, COSV60152520; called by muse, mutect2, varscan2
- GLUD2 | c.836G>T p.G279V | Missense Mutation (SNP) | VAF 68/138 reads (49%) | SIFT deleterious (0); PolyPhen possibly damaging (0.808); catalogued as COSV100047193; called by muse, mutect2, varscan2
- GSDMB | c.550C>T p.Q184* | Nonsense Mutation (SNP) | VAF 70/232 reads (30%) | catalogued as rs766961609, COSV58780351; called by muse, mutect2, varscan2
- HOXA11 | c.899A>T p.N300I | Missense Mutation (SNP) | VAF 53/232 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.963); catalogued as COSV99136163; called by muse, mutect2, varscan2
- HOXA11 | c.898A>C p.N300H | Missense Mutation (SNP) | VAF 52/229 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.963); catalogued as COSV99136167; called by muse, mutect2, varscan2
- HSD11B1 | c.88G>T p.E30* | Nonsense Mutation (SNP) | VAF 29/116 reads (25%) | catalogued as COSV99808428; called by muse, mutect2, varscan2
- HSD11B1 | c.88+1G>T p.X30_splice | Splice Site (SNP) | VAF 28/115 reads (24%) | catalogued as rs1172687424, COSV99808433; called by muse, mutect2, varscan2
- HTR5A | c.829G>A p.E277K | Missense Mutation (SNP) | VAF 53/125 reads (42%) | SIFT tolerated (0.1); PolyPhen probably damaging (0.92); catalogued as rs1205586113, COSV55282191, COSV55283276; called by muse, mutect2, varscan2
- IGSF8 | c.1778T>A p.V593D | Missense Mutation (SNP) | VAF 67/218 reads (31%) | SIFT deleterious (0); PolyPhen possibly damaging (0.731); catalogued as COSV58757790; called by muse, mutect2, varscan2
- IL13RA2 | c.975G>T p.W325C | Missense Mutation (SNP) | VAF 17/35 reads (49%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV54564768; called by muse, mutect2, varscan2
- IQGAP2 | c.1960G>T p.E654* | Nonsense Mutation (SNP) | VAF 18/86 reads (21%) | catalogued as COSV57171865; called by muse, mutect2, varscan2
- KDR | c.3502G>A p.A1168T | Missense Mutation (SNP) | VAF 12/41 reads (29%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.713); catalogued as COSV55762444, COSV55775606; called by muse, mutect2, varscan2
- KIF2B | c.1915G>T p.A639S | Missense Mutation (SNP) | VAF 32/113 reads (28%) | SIFT tolerated (0.13); PolyPhen benign (0.098); catalogued as COSV52129345, COSV52130855; called by muse, mutect2, varscan2
- KLRC2 | c.511T>C p.S171P | Missense Mutation (SNP) | VAF 12/46 reads (26%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.841); catalogued as COSV67899749; called by muse, mutect2
- LAT | c.28G>A p.V10M | Missense Mutation (SNP) | VAF 42/163 reads (26%) | SIFT tolerated, low confidence (0.07); PolyPhen benign (0.015); catalogued as rs200070316, COSV57954321; called by muse, mutect2, varscan2
- LTBP1 | c.4000+1G>A p.X1334_splice (on ENST00000404816 / NM_206943.4; = p.X1008_splice on NM_000627.4) | Splice Site (SNP) | VAF 94/265 reads (35%) | catalogued as COSV55378208; called by muse, mutect2, varscan2
- MAGI1 | c.538G>T p.G180C | Missense Mutation (SNP) | VAF 37/122 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV58322054, COSV58327645; called by muse, mutect2, varscan2
- MINDY4 | c.189G>T p.K63N | Missense Mutation (SNP) | VAF 21/73 reads (29%) | SIFT deleterious (0); PolyPhen possibly damaging (0.702); catalogued as COSV54673156; called by muse, mutect2, varscan2
- MMP1 | c.415C>A p.Q139K | Missense Mutation (SNP) | VAF 53/141 reads (38%) | SIFT tolerated (1); PolyPhen benign (0.012); catalogued as rs1282844660, COSV59510128, COSV59511219; called by muse, mutect2, varscan2
- MOV10 | c.32G>T p.R11L | Missense Mutation (SNP) | VAF 56/168 reads (33%) | SIFT tolerated (0.11); PolyPhen benign (0.031); catalogued as rs757439589, COSV54144976; called by muse, mutect2, varscan2
- MTHFSD | c.1025G>A p.R342Q (on ENST00000360900 / NM_001159377.2; = p.R341Q on NM_022764.3 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 9/27 reads (33%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs888448407, COSV59802781; called by muse, mutect2, varscan2
- NAV3 | c.4724G>T p.R1575L | Missense Mutation (SNP) | VAF 5/18 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs200507786, COSV57073690, COSV99891167; called by muse, mutect2, varscan2
- NOL4 | c.1526G>T p.R509L | Missense Mutation (SNP) | VAF 18/51 reads (35%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.991); catalogued as COSV52344423, COSV52349065; called by muse, mutect2, varscan2
- OR11H1 | c.732del p.C245Vfs*20 | Frame Shift Del (DEL) | VAF 35/161 reads (22%) | catalogued as COSV99421650; called by mutect2, pindel, varscan2
- OR2M3 | c.793del p.D265Ifs*21 | Frame Shift Del (DEL) | VAF 47/182 reads (26%) | catalogued as COSV71759181; called by mutect2, pindel, varscan2
- OR51A4 | c.571T>A p.C191S | Missense Mutation (SNP) | VAF 16/79 reads (20%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as COSV66749307; called by muse, mutect2, varscan2
- OR52J3 | c.559G>A p.A187T | Missense Mutation (SNP) | VAF 17/72 reads (24%) | SIFT deleterious (0); PolyPhen possibly damaging (0.889); catalogued as rs1222217746, COSV66746775; called by muse, mutect2, varscan2
- OR6C65 | c.131T>A p.I44N | Missense Mutation (SNP) | VAF 10/37 reads (27%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.986); catalogued as rs772661526, COSV65568373; called by muse, mutect2, varscan2
- OR9Q2 | c.758G>A p.G253D | Missense Mutation (SNP) | VAF 61/167 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (0.951); catalogued as COSV61111746; called by muse, mutect2, varscan2
- PAF1 | c.890G>T p.W297L | Missense Mutation (SNP) | VAF 96/306 reads (31%) | SIFT deleterious (0); PolyPhen possibly damaging (0.857); catalogued as COSV55393398; called by muse, mutect2, varscan2
- PAQR8 | c.23G>A p.R8H | Missense Mutation (SNP) | VAF 13/84 reads (15%) | SIFT tolerated (0.05); PolyPhen benign (0.01); catalogued as rs1195271205, COSV62442341; called by muse, mutect2, varscan2
- PCDHA8 | c.275G>A p.R92H | Missense Mutation (SNP) | VAF 168/740 reads (23%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.945); catalogued as COSV65336069; called by muse, varscan2
- PEX5L | c.1745C>G p.P582R | Missense Mutation (SNP) | VAF 88/297 reads (30%) | SIFT tolerated (0.23); PolyPhen benign (0.096); catalogued as COSV55843475, COSV99830310; called by muse, mutect2, varscan2
- PLPPR4 | c.2133C>A p.S711R | Missense Mutation (SNP) | VAF 16/56 reads (29%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.654); catalogued as COSV64565324, COSV64565634; called by muse, mutect2, varscan2
- POFUT2 | c.756G>T p.E252D | Missense Mutation (SNP) | VAF 90/325 reads (28%) | SIFT tolerated (0.41); PolyPhen benign (0.011); catalogued as rs1386455930, COSV57958652; called by muse, mutect2, varscan2
- PPM1B | c.809A>G p.N270S | Missense Mutation (SNP) | VAF 19/67 reads (28%) | SIFT tolerated (0.57); PolyPhen benign (0); catalogued as COSV56766182; called by muse, mutect2, varscan2
- PTPRD | c.369G>T p.R123S | Missense Mutation (SNP) | VAF 12/54 reads (22%) | SIFT tolerated (0.67); PolyPhen benign (0); catalogued as COSV61938440; called by muse, mutect2, varscan2
- PTPRM | c.614A>G p.Q205R | Missense Mutation (SNP) | VAF 50/142 reads (35%) | SIFT deleterious (0); PolyPhen benign (0.068); catalogued as COSV59854038; called by muse, mutect2, varscan2
- RARS1 | c.1123A>G p.I375V | Missense Mutation (SNP) | VAF 47/167 reads (28%) | SIFT tolerated (0.9); PolyPhen benign (0.028); catalogued as rs1451812591, COSV51562953; called by muse, mutect2, varscan2
- RELN | c.7643C>T p.S2548L | Missense Mutation (SNP) | VAF 62/218 reads (28%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.876); catalogued as rs139106600; called by muse, mutect2, varscan2
- RP1L1 | c.4321C>A p.P1441T | Missense Mutation (SNP) | VAF 263/773 reads (34%) | SIFT tolerated (0.16); PolyPhen benign (0.005); catalogued as COSV66754046; called by muse, mutect2, varscan2
- RPTN | c.1208A>T p.Y403F | Missense Mutation (SNP) | VAF 446/1405 reads (32%) | SIFT deleterious (0.01); PolyPhen benign (0.208); catalogued as COSV60166950; called by muse, mutect2, varscan2
- SEMA6A | c.2784C>A p.S928R | Missense Mutation (SNP) | VAF 42/135 reads (31%) | SIFT tolerated (0.63); PolyPhen benign (0.251); catalogued as COSV56710548; called by muse, mutect2, varscan2
- SETBP1 | c.3314G>T p.G1105V | Missense Mutation (SNP) | VAF 63/214 reads (29%) | SIFT tolerated (0.25); PolyPhen benign (0.058); catalogued as COSV56318819; called by muse, mutect2, varscan2
- SH2B1 | c.235G>A p.E79K | Missense Mutation (SNP) | VAF 7/74 reads (9%) | SIFT deleterious (0); PolyPhen possibly damaging (0.46); catalogued as COSV59462158, COSV59462408; called by muse, varscan2
- SNCAIP | c.901C>A p.L301I | Missense Mutation (SNP) | VAF 46/141 reads (33%) | SIFT tolerated (0.26); PolyPhen benign (0.006); catalogued as COSV54407500; called by muse, mutect2, varscan2
- SNTG1 | c.1142G>T p.W381L | Missense Mutation (SNP) | VAF 17/76 reads (22%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.953); catalogued as COSV99386992; called by muse, mutect2, varscan2
- SNTG1 | c.1143G>T p.W381C | Missense Mutation (SNP) | VAF 17/75 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); catalogued as COSV52443841, COSV99386998; called by muse, mutect2, varscan2
- SPAG17 | c.4306G>T p.D1436Y | Missense Mutation (SNP) | VAF 23/88 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV60456663; called by muse, mutect2, varscan2
- SPATA13 | c.448G>T p.V150F | Missense Mutation (SNP) | VAF 200/498 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (0.969); catalogued as rs1566193583, COSV57977021; called by muse, mutect2, varscan2
- SPTA1 | c.2782G>A p.G928S | Missense Mutation (SNP) | VAF 29/89 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV63751638; called by muse, mutect2, varscan2
- TAOK2 | c.1557G>T p.E519D | Missense Mutation (SNP) | VAF 35/91 reads (38%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.989); catalogued as COSV54234872, COSV54241081; called by muse, mutect2, varscan2
- TECTA | c.854G>T p.C285F | Missense Mutation (SNP) | VAF 60/147 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV50700313; called by muse, mutect2, varscan2
- THSD4 | c.1999G>A p.E667K | Missense Mutation (SNP) | VAF 210/659 reads (32%) | SIFT tolerated (0.15); PolyPhen possibly damaging (0.877); catalogued as rs747954248, COSV55967239; called by muse, mutect2, varscan2
- TMTC2 | c.456G>T p.L152F | Missense Mutation (SNP) | VAF 25/75 reads (33%) | SIFT tolerated (0.59); PolyPhen benign (0.208); catalogued as COSV58265286; called by muse, mutect2, varscan2
- TRIM22 | c.1319C>T p.P440L | Missense Mutation (SNP) | VAF 82/231 reads (35%) | SIFT tolerated (0.13); PolyPhen possibly damaging (0.622); catalogued as COSV66090630; called by muse, mutect2, varscan2
- UBE3D | c.46G>T p.G16* | Nonsense Mutation (SNP) | VAF 14/31 reads (45%) | catalogued as COSV52709074; called by muse, mutect2, varscan2
- USH2A | c.7321C>T p.P2441S | Missense Mutation (SNP) | VAF 21/69 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV56356084; called by muse, mutect2, varscan2
- XPO7 | c.2296G>T p.A766S | Missense Mutation (SNP) | VAF 15/46 reads (33%) | SIFT tolerated (0.59); PolyPhen benign (0.015); catalogued as COSV53013863; called by muse, mutect2, varscan2
- ZBTB16 | c.1613G>T p.R538L | Missense Mutation (SNP) | VAF 24/92 reads (26%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.707); catalogued as COSV60091604, COSV60093642; called by muse, mutect2, varscan2
- ZNF287 | c.355G>A p.E119K | Missense Mutation (SNP) | VAF 50/96 reads (52%) | SIFT deleterious (0); PolyPhen benign (0.281); catalogued as COSV67688333; called by muse, mutect2, varscan2
- ZNF43 | c.1349G>T p.G450V | Missense Mutation (SNP) | VAF 19/58 reads (33%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.584); catalogued as COSV100732008; called by muse, mutect2, varscan2
- ZNF43 | c.1348G>T p.G450* | Nonsense Mutation (SNP) | VAF 19/58 reads (33%) | catalogued as COSV100732009; called by muse, mutect2, varscan2
- ZSCAN1 | c.408G>T p.W136C | Missense Mutation (SNP) | VAF 182/574 reads (32%) | SIFT tolerated (0.18); PolyPhen benign (0); catalogued as rs767685924, COSV56603552; called by muse, mutect2, varscan2
- CHD2 | c.1320_1324del p.C440* | Frame Shift Del (DEL) | VAF 47/144 reads (33%) | called by mutect2, pindel, varscan2
- MAGEL2 | c.2970del p.V991* | Frame Shift Del (DEL) | VAF 19/95 reads (20%) | called by mutect2, pindel, varscan2
- ADCY8 | c.3522C>T p.V1174= | Silent (SNP) | VAF 61/194 reads (31%) | catalogued as COSV53903793; called by muse, mutect2, varscan2
- ASTN1 | c.2958C>A p.T986= | Silent (SNP) | VAF 30/104 reads (29%) | catalogued as COSV62495142; called by muse, mutect2, varscan2
- CDK1 | c.54G>C p.V18= | Silent (SNP) | VAF 41/116 reads (35%) | catalogued as COSV57349391; called by muse, mutect2, varscan2
- GART | c.2289T>C p.I763= | Silent (SNP) | VAF 150/515 reads (29%) | catalogued as COSV67818430; called by muse, mutect2, varscan2
- GLG1 | c.1167C>T p.N389= | Silent (SNP) | VAF 17/174 reads (10%) | catalogued as COSV52665825; called by muse, mutect2
- INPPL1 | c.2475C>T p.V825= | Silent (SNP) | VAF 62/174 reads (36%) | catalogued as rs371376566; called by muse, mutect2, varscan2
- LILRB1 | c.918C>T p.G306= (on ENST00000427581; = p.G270= on NM_006669.6) | Silent (SNP) | VAF 91/271 reads (34%) | catalogued as rs372648620; called by muse, mutect2, varscan2
- LRGUK | c.135C>T p.P45= | Silent (SNP) | VAF 86/265 reads (32%) | catalogued as COSV53636679; called by muse, mutect2, varscan2
- MYO7B | c.5499G>A p.Q1833= | Silent (SNP) | VAF 8/24 reads (33%) | catalogued as COSV61442466; called by muse, mutect2, varscan2
- NPTXR | c.1473C>T p.F491= | Silent (SNP) | VAF 20/76 reads (26%) | catalogued as rs145163836; called by muse, mutect2, varscan2
- PDCD1LG2 | c.18A>C p.L6= | Silent (SNP) | VAF 8/205 reads (4%) | catalogued as COSV67204393; called by muse, mutect2
- PLXNA4 | c.168G>T p.V56= | Silent (SNP) | VAF 43/148 reads (29%) | catalogued as COSV58117864; called by muse, mutect2, varscan2
- PRR5 | c.39C>T p.G13= | Silent (SNP) | VAF 12/28 reads (43%) | catalogued as COSV50059502; called by muse, mutect2, varscan2
- STAP2 | c.735G>T p.L245= | Silent (SNP) | VAF 28/121 reads (23%) | catalogued as COSV55695634; called by muse, mutect2, varscan2
- TRPM8 | c.84G>A p.A28= | Silent (SNP) | VAF 28/93 reads (30%) | catalogued as rs149381224; called by muse, mutect2, varscan2
- TTC37 | c.4101A>G p.R1367= | Silent (SNP) | VAF 22/44 reads (50%) | catalogued as COSV62454429; called by muse, mutect2, varscan2
- VCAN | c.1644T>C p.Y548= | Silent (SNP) | VAF 38/117 reads (32%) | catalogued as COSV54102753; called by muse, mutect2, varscan2
- WIPF1 | c.432A>T p.P144= | Silent (SNP) | VAF 47/163 reads (29%) | catalogued as COSV55813438; called by muse, mutect2, varscan2
- FXYD6P3 | n.36C>A | RNA (SNP) | VAF 60/124 reads (48%) | called by muse, mutect2, varscan2
- GLYATL1 | c.-55C>A | 5'UTR (SNP) | VAF 19/51 reads (37%) | catalogued as COSV100265399, COSV55608441; called by muse, varscan2
